Somatic mutation profile of tumor specimen TCGA-G9-6364-01A (aliquot TCGA-G9-6364-01A-21D-1786-08) from TCGA case TCGA-G9-6364, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.8 years (26,603 days).
Specimen TCGA-G9-6364-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dd0c09d-fd13-4746-8b5d-5b2a10af1d45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6364-10A (Blood Derived Normal), aliquot TCGA-G9-6364-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/320ab13d-e91d-4b27-bb42-d491379b3c4f

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 14, Silent 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3B2 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55614075; called by muse, mutect2
- BBS10 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV53888913; called by muse, mutect2, varscan2
- BEND6 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs866942036, COSV66070290; called by muse, mutect2
- C20orf194 | c.3261G>C p.Q1087H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52702449; called by muse, mutect2, varscan2
- CAPN13 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as rs893474111, COSV54435146; called by muse, mutect2, varscan2
- CHAF1A | c.2798C>T p.S933F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV56676211; called by muse, mutect2, varscan2
- DDX60L | c.4226A>G p.Y1409C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV52721539; called by muse, mutect2
- FZD6 | c.1453A>G p.I485V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.08); catalogued as COSV62472608; called by muse, mutect2, varscan2
- GRM4 | c.1708C>T p.R570C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1230852056, COSV100946075, COSV65219354; called by muse, mutect2, varscan2
- IQGAP1 | c.3817C>G p.P1273A | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV51591141; called by muse, mutect2, varscan2
- NGLY1 | c.941A>G p.N314S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748299536, COSV54990920; called by muse, mutect2, varscan2
- RPS6KA5 | c.1570A>C p.I524L | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.873); catalogued as COSV56225447; called by muse, mutect2, varscan2
- SLK | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59829027; called by muse, mutect2, varscan2
- TMEM184C | c.165T>G p.F55L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56854730; called by muse, mutect2, varscan2
- CD68 | c.186_187del p.H62Qfs*35 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by pindel, varscan2
- ZAN | c.1996del p.E666Rfs*335 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- SLC34A2 | c.2067C>T p.A689= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV65943093; called by muse, mutect2, varscan2
- SPTBN1 | c.111G>A p.A37= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs778135869, COSV63344902; called by muse, mutect2, varscan2
- XPO4 | c.280C>A p.R94= | Silent (SNP) | VAF 10/293 reads (3%) | catalogued as COSV55013130, COSV99689272; called by muse, mutect2
